Somatic mutation profile of tumor specimen MP2PRT-PAVAWE-TBP1-A (aliquot MP2PRT-PAVAWE-TBP1-A-1-0-D-A820-36) from MP2PRT case MP2PRT-PAVAWE, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Blood; Age at diagnosis: 1.6 years (586 days).
Specimen MP2PRT-PAVAWE-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e45d913e-0990-4331-8150-7f3852cbffbc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVAWE-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVAWE-NB1-A-1-0-D-A820-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c4f9020e-d50d-4ed2-87cd-a7c83071ddae

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 4, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACAD10 | c.1951G>A p.G651S | Missense Mutation (SNP) | VAF 32/574 reads (6%) | SIFT tolerated (0.77); PolyPhen benign (0.001); catalogued as rs983953065, COSV58161258; called by muse, mutect2
- AATF | c.1327C>G p.Q443E | Missense Mutation (SNP) | VAF 13/357 reads (4%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2
- ATG9B | c.1178G>T p.S393I | Missense Mutation (SNP) | VAF 20/604 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- OTOG | c.4771C>G p.P1591A | Missense Mutation (SNP) | VAF 33/699 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.048); called by muse, mutect2
- KCNH2 | c.366C>T p.V122= | Silent (SNP) | VAF 24/613 reads (4%) | called by muse, mutect2
